Somatic mutation profile of tumor specimen TCGA-D6-A6EQ-01A (aliquot TCGA-D6-A6EQ-01A-11D-A31L-08) from TCGA case TCGA-D6-A6EQ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 57.2 years (20,876 days).
Specimen TCGA-D6-A6EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f7a52a1-19a1-4098-9814-495263a350a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-A6EQ-10A (Blood Derived Normal), aliquot TCGA-D6-A6EQ-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/591868a2-ddab-4f56-8d70-1d9f76651a1e

The open-access MAF lists 100 somatic variants for this specimen: 78 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 19, Nonsense Mutation 4, Frame Shift Del 2, Intron 1, 3'Flank 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADH1C | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs78241133, COSV101565156; called by muse, mutect2, varscan2
- AK5 | c.226C>T p.R76W (on ENST00000354567 / NM_174858.3; = p.R50W on NM_012093.4) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs763885359, COSV100481324; called by muse, mutect2, varscan2
- ANXA1 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs543730068, COSV99973773; called by muse, mutect2, varscan2
- AOC1 | c.1970A>T p.N657I | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100710580; called by muse, mutect2, varscan2
- ARID2 | c.3778G>T p.E1260* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV57606696; called by muse, mutect2, varscan2
- ATF7IP | c.3259C>G p.R1087G | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53768255, COSV99661141; called by muse, mutect2, varscan2
- BCORL1 | c.4394C>T p.S1465F | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99498319; called by muse, mutect2, varscan2
- BMP3 | c.961T>C p.Y321H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99261329; called by muse, mutect2, varscan2
- CBARP | c.1108G>A p.D370N (on ENST00000382477; = p.D350N on NM_152769.3) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV99289301; called by muse, mutect2, varscan2
- CCDC102A | c.761C>G p.A254G | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV99264763; called by muse, mutect2, varscan2
- CD27 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99868896; called by muse, mutect2, varscan2
- CFAP69 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100289732; called by muse, mutect2, varscan2
- CIZ1 | c.1048T>A p.S350T | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV99476602; called by muse, mutect2, varscan2
- CNGB3 | c.2008G>C p.E670Q | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV100181094, COSV60686241; called by muse, mutect2, varscan2
- COPRS | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs777823563, COSV100188324, COSV56632729; called by muse, mutect2, varscan2
- CSMD3 | c.3074A>G p.D1025G (on ENST00000297405 / NM_001363185.1; = p.D921G on NM_052900.3) | Missense Mutation (SNP) | VAF 95/189 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as rs1481906651, COSV99823151; called by muse, mutect2, varscan2
- CXCL1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101203902, COSV101203933; called by muse, mutect2, varscan2
- CYB5RL | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV55279599, COSV99838827; called by muse, mutect2, varscan2
- CYP2C8 | c.1444T>C p.S482P | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV100987871; called by muse, mutect2
- CYP4Z1 | c.1442G>T p.R481M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100497502; called by muse, mutect2, varscan2
- DLX5 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99756191; called by muse, mutect2, varscan2
- DMP1 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs138537025; called by muse, mutect2, varscan2
- DNAH11 | c.8021C>T p.S2674L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.575); catalogued as COSV100176644, COSV100176917; called by muse, mutect2, varscan2
- DNAH17 | c.10429G>A p.A3477T | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101101287; called by muse, mutect2
- E2F3 | c.1397G>C p.*466Sext*5 | Nonstop Mutation (SNP) | VAF 53/113 reads (47%) | catalogued as COSV60896314; called by muse, mutect2, varscan2
- EFCAB12 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.167); catalogued as COSV100394444; called by muse, mutect2, varscan2
- ELSPBP1 | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100353477; called by muse, mutect2, varscan2
- ENPP1 | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100719359; called by muse, mutect2, varscan2
- FMN2 | c.4935C>G p.F1645L | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100142311; called by muse, mutect2, varscan2
- GFAP | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.053); catalogued as rs552590923, COSV53652239; called by muse, mutect2, varscan2
- GPR61 | c.1070T>C p.V357A | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100879815; called by muse, mutect2, varscan2
- HOXB5 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs1453457823, COSV99494329; called by muse, mutect2, varscan2
- HPR | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.149); catalogued as COSV99930748; called by muse, mutect2
- INTS5 | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs747832179, COSV100399424; called by muse, mutect2, varscan2
- KCNB2 | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 102/205 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV101578641; called by muse, mutect2, varscan2
- KIF13A | c.5323G>A p.D1775N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.009); catalogued as rs370748706; called by muse, mutect2, varscan2
- KRTAP15-1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 50/145 reads (34%) | catalogued as rs145057150; called by muse, mutect2, varscan2
- LPGAT1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV100878062; called by muse, mutect2
- LRP3 | c.2291A>T p.D764V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV99471952; called by muse, varscan2
- MCTP1 | c.2969C>A p.P990Q | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100386107; called by muse, mutect2, varscan2
- MKI67 | c.3269G>C p.R1090T | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as rs144881533; called by muse, mutect2, varscan2
- MNDA | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1558057358, COSV100933230; called by muse, varscan2
- MUC6 | c.6104C>T p.S2035F | Missense Mutation (SNP) | VAF 74/643 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV101424386; called by muse, varscan2
- NFRKB | c.3130G>A p.V1044M (on ENST00000446488 / NM_001143835.2; = p.V1069M on NM_006165.3) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.903); catalogued as rs1200157931, COSV100451764; called by muse, mutect2, varscan2
- NRXN1 | c.333C>G p.D111E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV101276275, COSV68015915; called by muse, mutect2, varscan2
- OBSCN | c.13704G>T p.Q4568H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99471771; called by muse, mutect2, varscan2
- OR13G1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV62944551; called by muse, mutect2, varscan2
- OR2M5 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV100822727; called by muse, varscan2
- PDIA4 | c.1279G>T p.D427Y (on ENST00000286091 / NM_001371244.1; = p.D426Y on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV53724578, COSV99618245; called by muse, mutect2, varscan2
- PKD1 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs569768187, CM057348, BM1377218; called by muse, varscan2
- PLEKHG5 | c.1780del p.E594Kfs*6 (on ENST00000400915 / NM_001042663.3; = p.E557Kfs*6 on NM_020631.6) | Frame Shift Del (DEL) | VAF 27/98 reads (28%) | catalogued as COSV61068093; called by mutect2, pindel, varscan2
- PREX2 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.063); catalogued as rs1418006656, COSV99904662; called by muse, mutect2
- RALGAPA2 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99173115; called by muse, mutect2
- SLC16A9 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 22/117 reads (19%) | catalogued as COSV101264286; called by muse, mutect2, varscan2
- SLC25A17 | c.731T>C p.L244S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.14); catalogued as COSV99610485; called by muse, mutect2, varscan2
- SLC35A5 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99656683; called by muse, mutect2, varscan2
- SLC66A1 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100913152; called by muse, mutect2
- SPATA16 | c.1018A>T p.I340L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV100650838; called by muse, mutect2, varscan2
- SPON1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100115175; called by muse, mutect2, varscan2
- STX11 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62448931; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.393); catalogued as rs1273447912; called by muse, mutect2, varscan2
- TEKT1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs1220098870, COSV100105891; called by muse, mutect2, varscan2
- TNFAIP1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99134665; called by muse, mutect2, varscan2
- TNFRSF14 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs774857719, COSV100859035; called by muse, varscan2
- TRIP11 | c.1451A>G p.N484S | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1237394434, COSV99970269; called by muse, mutect2, varscan2
- TTN | c.21289G>A p.E7097K (on ENST00000591111; = p.E6170K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | PolyPhen benign (0.423); catalogued as COSV100592204; called by muse, mutect2, varscan2
- TYSND1 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs1343629341, COSV54644318; called by muse, mutect2
- UBAP2 | c.852C>G p.I284M | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV100670865; called by muse, mutect2
- UNC13A | c.5098G>A p.A1700T | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99406949; called by muse, varscan2
- VCAN | c.9965G>A p.R3322K | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54108109, COSV99424457; called by muse, mutect2, varscan2
- XPNPEP2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV100941134; called by muse, mutect2, varscan2
- XPR1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100851410; called by muse, mutect2, varscan2
- ACACA | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- EVPL | c.5879_5892del p.L1960Qfs*2 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | called by mutect2, pindel, varscan2
- IGHV3-66 | c.19T>G p.W7G | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); called by muse, varscan2
- MAGEB6B | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF84 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ABCC12 | c.630G>A p.K210= | Silent (SNP) | VAF 78/264 reads (30%) | catalogued as COSV100252100; called by muse, mutect2, varscan2
- ARFGEF3 | c.6477C>T p.R2159= | Silent (SNP) | VAF 59/132 reads (45%) | catalogued as COSV99292150; called by muse, mutect2, varscan2
- ARHGAP22 | c.609G>A p.V203= | Silent (SNP) | VAF 93/283 reads (33%) | catalogued as COSV99984352; called by muse, mutect2, varscan2
- BCORL1 | c.4395C>T p.S1465= | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as rs775481616, COSV99498323; called by muse, mutect2, varscan2
- CST9L | c.255T>A p.T85= | Silent (SNP) | VAF 46/231 reads (20%) | catalogued as COSV100980817, COSV65407617; called by muse, mutect2, varscan2
- DLG5 | c.2574A>T p.P858= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV100967226; called by muse, mutect2, varscan2
- DNM1 | c.780C>T p.L260= | Silent (SNP) | VAF 95/206 reads (46%) | catalogued as rs749030612, COSV100359398; called by muse, mutect2, varscan2
- FKBP10 | c.1470C>A p.P490= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as COSV99505020; called by muse, mutect2, varscan2
- KAT7 | c.729C>T p.N243= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99371568; called by muse, mutect2, varscan2
- MCTP1 | c.2970A>T p.P990= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV100386106; called by muse, mutect2, varscan2
- NAV3 | c.5814G>A p.L1938= (on ENST00000397909 / NM_001024383.2; = p.L1916= on NM_014903.6) | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs751707040, COSV57076761, COSV99886566; called by muse, mutect2, varscan2
- NRXN1 | c.4017G>C p.P1339= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as COSV100639721, COSV60514279; called by muse, mutect2, varscan2
- OR1L4 | c.591G>A p.Q197= | Silent (SNP) | VAF 58/543 reads (11%) | catalogued as COSV99413768; called by muse, varscan2
- OR6T1 | c.768C>T p.I256= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as COSV100189698; called by muse, mutect2, varscan2
- PEX11B | c.630C>T p.D210= | Silent (SNP) | VAF 51/158 reads (32%) | catalogued as rs782043450, COSV65199264; called by muse, mutect2, varscan2
- PPFIA2 | c.2508T>C p.R836= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as COSV100331479; called by muse, mutect2, varscan2
- PPIL2 | c.309C>T p.C103= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100622410; called by muse, mutect2, varscan2
- SYNJ1 | c.3810G>A p.S1270= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs755437097, COSV100448881; called by muse, mutect2, varscan2
- SYT16 | c.1581C>A p.I527= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV101413448; called by muse, varscan2
- AL136982.4 | n.646G>C | RNA (SNP) | VAF 69/189 reads (37%) | called by muse, mutect2, varscan2
- IGKV2D-30 | chr2:89937680 del C | 3'Flank (DEL) | VAF 20/100 reads (20%) | called by mutect2, varscan2
- RGPD1 | c.48+5893G>T | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as COSV67962345; called by muse, mutect2, varscan2
